Somatic mutation profile of tumor specimen C3L-08314-01 (aliquot CPT0503640006) from CPTAC case C3L-08314, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 70.1 years (25,593 days).
Specimen C3L-08314-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2844b315-de0c-49ea-98e9-1f7428f52a8e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-08314-31 (Blood Derived Normal), aliquot CPT0503790002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4dcaca48-43fa-4ca9-8109-657d0d81a620

The open-access MAF lists 34 somatic variants for this specimen: 21 protein-altering or splice-affecting, 13 silent.
By variant classification: Missense Mutation 20, Silent 13, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B3GNT6 | c.989G>A p.R330Q | Missense Mutation (SNP) | VAF 22/620 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1555027824, COSV62828077; called by muse, mutect2
- EXOC2 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 41/383 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as rs1048821721; called by muse, mutect2, varscan2
- LIPI | c.1036T>C p.F346L | Missense Mutation (SNP) | VAF 11/314 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV60708443; called by muse, mutect2
- PCDHA10 | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 24/746 reads (3%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as COSV100248191; called by muse, mutect2
- PTK6 | c.950A>G p.N317S | Missense Mutation (SNP) | VAF 18/552 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53916818; called by muse, mutect2
- STAT5B | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs781121963, COSV53183352; called by muse, varscan2
- AQP1 | c.71T>A p.F24Y | Missense Mutation (SNP) | VAF 18/500 reads (4%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.992); called by muse, mutect2
- DOCK10 | c.3986T>G p.L1329* | Nonsense Mutation (SNP) | VAF 22/323 reads (7%) | called by muse, mutect2
- EFCC1 | c.1503G>C p.Q501H | Missense Mutation (SNP) | VAF 42/553 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.225); called by muse, mutect2
- FLRT2 | c.892A>T p.N298Y | Missense Mutation (SNP) | VAF 11/348 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.378); called by muse, mutect2
- GOLGA8G | c.187T>C p.C63R | Missense Mutation (SNP) | VAF 6/150 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2
- IFNA10 | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 22/514 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- KIAA1210 | c.2597G>T p.C866F | Missense Mutation (SNP) | VAF 9/272 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2
- LSM12 | c.66G>T p.E22D | Missense Mutation (SNP) | VAF 12/376 reads (3%) | SIFT tolerated (0.82); PolyPhen benign (0.021); called by muse, mutect2
- MUC22 | c.2321A>G p.E774G | Missense Mutation (SNP) | VAF 47/737 reads (6%) | SIFT tolerated (0.19); called by muse, mutect2
- NAA25 | c.499A>G p.N167D | Missense Mutation (SNP) | VAF 12/320 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.118); called by muse, mutect2
- PEG3 | c.4576A>C p.T1526P | Missense Mutation (SNP) | VAF 21/393 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2
- RECQL5 | c.118G>C p.A40P | Missense Mutation (SNP) | VAF 12/272 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- TMEM200C | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 24/584 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2
- TRMT2B | c.812G>C p.G271A | Missense Mutation (SNP) | VAF 20/227 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2
- VIRMA | c.3908C>A p.S1303Y | Missense Mutation (SNP) | VAF 34/289 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- ALPG | c.567G>A p.S189= | Silent (SNP) | VAF 36/637 reads (6%) | catalogued as rs772670586, COSV54967400; called by muse, mutect2
- AQP4 | c.399C>T p.L133= | Silent (SNP) | VAF 18/462 reads (4%) | called by muse, mutect2
- BAZ1B | c.1032G>A p.K344= | Silent (SNP) | VAF 13/377 reads (3%) | catalogued as rs368184813; called by muse, mutect2
- BICRA | c.1023C>T p.N341= | Silent (SNP) | VAF 18/570 reads (3%) | catalogued as rs1312677395; called by muse, mutect2
- COL25A1 | c.1275C>T p.A425= | Silent (SNP) | VAF 14/394 reads (4%) | catalogued as COSV101211618; called by muse, mutect2
- DSEL | c.891C>G p.V297= | Silent (SNP) | VAF 22/630 reads (3%) | catalogued as COSV100025468; called by muse, mutect2
- ENPP1 | c.84C>A p.G28= | Silent (SNP) | VAF 22/326 reads (7%) | called by muse, mutect2
- KPTN | c.378C>T p.N126= | Silent (SNP) | VAF 15/386 reads (4%) | called by muse, mutect2
- PCDHA1 | c.1302G>A p.S434= | Silent (SNP) | VAF 17/590 reads (3%) | catalogued as rs144742806, COSV65377815; called by muse, mutect2
- SASH1 | c.3072C>A p.G1024= | Silent (SNP) | VAF 19/724 reads (3%) | called by muse, mutect2
- TRPM2 | c.3366A>G p.L1122= | Silent (SNP) | VAF 17/455 reads (4%) | called by muse, mutect2
- ULK4 | c.474A>C p.A158= | Silent (SNP) | VAF 16/437 reads (4%) | called by muse, mutect2
- ZNF320 | c.468T>G p.T156= | Silent (SNP) | VAF 14/439 reads (3%) | called by muse, mutect2
